Surgical pathology report (de-identified scan), TCGA case TCGA-53-A4EZ, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site University of Miami, specimen TCGA-53-A4EZ-01A (Primary Tumor).

[page 1 of 4]
Surgical Pathology Report

Name:	XX	Case #:	XX
DOB:	XX(Age:	Collected:	XX
Gender:	M	Received:	XX
MRN:	XX	Reported:	XX
Location:	XX	TBCF#:	
Physician:	XX		

Pathologic Interpretation:

A. LYMPH NODE 4R:

One (1) lymph node with no malignancy seen.

B. LYMPH NODE 4L:

One (1) lymph node with no malignancy seen.

C. LYMPH NODE 7:

One (1) lymph node with no malignancy seen.

D. LYMPH NPDE STATION 8:

One (1) lymph node with no malignancy seen.

E. LYMPH NODE STATION 9:

One (1) lymph node with no malignancy seen.

F. LYMPH NODE STATION 10:

One (1) lymph node with no malignancy seen.

G. LEFT UPPER LOBE LUNG:

POORLY DIFFERENTIATED ADENOCARCINOMA.

One of four lymph nodes with METASTATIC CARCINOMA.

See tumor summary.

H. LYMPH NODE STATION 5:

One (1) lymph ode with no malignancy seen.

Pathology Cancer Case Summary: LUNG: RESECTION

Specimen: Lobe(s) of lung (specify): Left upper

Procedure: Lobectomy

Specimen Integrity: intact

Specimen Laterality: Left

Tumor Site: Upper lobe

Tumor Size:

1CB-0-3
adenocarcinoma, acinar 8550/3
Site: lung, upper lobe C34.1
hw
10/1/12

[page 2 of 4]
Dimension: 4.5 cm

Additional dimensions: 3.5 x 3.0 cm

Tumor Focality: Unifocal

Histologic Type: Adenocarcinoma, Acinar

Histologic Grade: G3: Poorly differentiated

Visceral Pleural Invasion: Present

Tumor Extension: Not applicable

Margins:

Bronchial Margin: Uninvolved by invasive carcinoma

Vascular Margin: Uninvolved by invasive carcinoma

Lymph-Vascular Invasion: Present

Lymph Nodes: Not identified

Pathologic Staging (pTNM): pT2a, N1, Mx

PRIMARY TUMOR:

pT2a: Tumor greater than 3 cm, but 5 cm or less in greatest dimension, surrounded by lung or visceral pleura, without

bronchoscopic evidence of invasion more proximal than the lobar bronchus (ie, not in the main bronchus)

REGIONAL LYMPH NODES:

pN1: Metastasis in ipsilateral peribronchial and/or ipsilateral hilar lymph nodes, and intrapulmonary nodes, including

involvement by direct extension

Specify: Number examined: 11

Number involved: 1

DISTANT METASTASIS:

Not applicable

Ancillary Studies:

Epidermal growth factor receptor (EGFR) analysis: Pending on block G5

KRAS mutational analysis: Pending on block G5

NOTE: Some immunohistochemical antibodies are analyte specific reagents (ASRs) validated by our laboratory. These ASRs are clinically useful indicators that do not require FDA approval. These clones are used: IDS=ER, Pgr 636=PR, A485=HER2, H-11=EGFR. All immunohistochemical stains are used with formalin or molecular fixed, paraffin embedded tissue. Detection is by Envision Method. The results are read by a pathologist as positive or negative.

As the attending pathologist, I attest that I: (i) Examined the relevant preparation(s) for the specimen(s); and (ii) Rendered the diagnosis(es).

XX, MD

Electronically Signed Out By

XX

Intraoperative Consultation

A. Lymph node 4R, FS: Negative lymph node. Reviewed with Dr XX

B. Lymph node 4L, FS: Negative lymph node. Reviewed with Dr XX

C. Lymph node, station 7, FS: Negative lymph node. Reviewed with Dr XX

XX, MD

Clinical History:

Lung cancer

[page 3 of 4]
Operation Performed

Bronchoscopy, cervical mediastinoscopy, possible left thoracotomy

Pre Operative Diagnosis:

None Provided

Specimen(s) Received/Processing Information:
Codes:**Fee**

A: LYMPH NODE 4R, FS Frozen section x 1, FS Perm x 1, Touch Prep Histology x 1, Touch Prep Histology x 1 B: LYMPH NODE 4L, FS Frozen section x 1, FS Perm x 1 C: LYMPH NODE 7, FS Frozen section x 1, FS Perm x 1 D: LYMPH NPDE STATION 8 H&E, Initial x 1 E: LYMPH NODE STATION 9 H&E, Initial x 1 F: LYMPH NODE STATION 10 H&E, Initial x 1 G: LEFT UPPER LOBE LUNG H&E, Initial x 1, H&E, Initial x 1, H&E, Initial x 1, H&E, Initial x 1, H&E, Initial x 1, H&E, Initial x 1, H&E, Initial x 1, H&E, Initial x 1, Anaplastic Lymphoma Kinase x 1, EGFR Mutation Detection-Cytogenetics x 1 H: LYMPH NODE STATION 5 H&E, Initial x 1, H&E, Initial x 1	
---	--

Gross Description:

- A. Received fresh are three tan-brown lymph nodes measuring 0.3 x 0.2 x 0.2 cm. Submitted in toto for frozen section in one cassette.
- B. Received fresh are two dark brown lymph nodes measuring 0.3 x 0.2 x 0.2 cm in aggregate. Submitted in toto in one cassette for frozen section.
- C. Received fresh are two dark brown lymph nodes measuring 0.2 x 0.2 x 0.2 cm in aggregate. Submitted in toto in one cassette for frozen section.
- D. Received in formalin is a lymph node measuring 1.0 x 0.6 x 0.4 cm. Bisected and submitted in toto in one cassette.
- E. Received in formalin is a lymph node measuring 0.8 x 0.5 x 0.4 cm. Bisected and submitted in toto in one cassette.
- F. Received in formalin is a lymph node measuring 0.5 x 0.5 x 0.2 cm. Submitted in toto in one cassette.
- G. Received in formalin labeled "Left upper lobe lung" is a 235 gram lobe segment measuring 21.0 x 11.5 x 3.0 cm. The pleura is mottled dark red-brown and there is an area of puckering measuring 2.5 x 1.0 cm. It is inked black. Sectioning shows a well circumscribed tan-white soft and necrotic lesion, measuring 4.5 x 3.5 x 3.0 cm and is 2.0 cm away from the main bronchus margin and 2.5 cm away from the vascular margin. The lesion

[page 4 of 4]
does not appear to grossly extend into either the vasculature or bronchus. The remaining lung parenchyma is dark red and hemorrhagic and appears to be uninvolved. Seven possible lymph nodes were found. Representative sections are submitted as follows in eight cassettes.

- Cassette #1 The bronchial and vascular margin
- Cassette #2 Representative section of the tumor in relation to vein
- Cassette #3 Representative section of tumor in relation to normal lung parenchyma
- Cassettes #4&5 Representative sections of tumor in relationship to pleura
- Cassette #6 One lymph node bisected and submitted in toto
- Cassette #7 Three lymph nodes in toto
- Cassette #8 Three lymph nodes in toto

H. Received in formalin are six possible lymph nodes, the largest measuring 0.2 x 0.2 x 0.2 cm. Submitted in toto in two cassettes.

XX, MD

9/19/12

Source: NCI Genomic Data Commons file a0bfcff6-d3e6-4c9d-86d8-d0e7c5e825be (TCGA-53-A4EZ.E4CB6C1D-9774-47BE-989E-F9CD05D9EED8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).